Somatic mutation profile of cancer-model specimen HCM-CSHL-0257-C18-85A (3D Organoid; aliquot HCM-CSHL-0257-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0257-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-CSHL-0257-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d72a57cb-6da4-431e-ba46-2752df5920fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0257-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0257-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3075dce-4877-488b-9147-ed0272a756b7

The open-access MAF lists 153 somatic variants for this specimen: 113 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 38, Nonsense Mutation 6, Frame Shift Ins 3, Splice Region 2, Splice Site 1, Intron 1, In Frame Del 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 60/60 reads (100%) | catalogued as rs137854573, CM920034, COSV57321615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 306/308 reads (99%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACKR2 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757492481; called by muse, mutect2, varscan2
- ACTBL2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 112/250 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.385); catalogued as rs747561123, COSV70661337; called by muse, mutect2, varscan2
- ANKRD45 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60960360; called by muse, mutect2, varscan2
- APBB1 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 167/452 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs1453333478; called by muse, mutect2, varscan2
- APOF | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 74/368 reads (20%) | catalogued as rs932985798, COSV58474359; called by muse, mutect2, varscan2
- ARHGAP15 | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV54522824; called by muse, mutect2
- ARHGAP23 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 399/1452 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs1272252232; called by muse, mutect2, varscan2
- ARHGEF18 | c.1911C>T p.I637= (on ENST00000359920 / NM_001130955.2; = p.I533= on NM_015318.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 61/321 reads (19%) | catalogued as rs1396995978; ClinVar: likely benign; called by muse, mutect2, varscan2
- BSN | c.11026C>T p.R3676C | Missense Mutation (SNP) | VAF 434/626 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749636971, COSV56521370; called by muse, mutect2, varscan2
- CACNA1E | c.6055C>T p.R2019C (on ENST00000367573 / NM_001205293.3; = p.R1976C on NM_000721.4) | Missense Mutation (SNP) | VAF 230/346 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259782913, COSV62388920; called by muse, mutect2, varscan2
- CACNA2D4 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 155/604 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs377191684; called by muse, mutect2, varscan2
- CDC25A | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs757533603, COSV56770671; called by muse, mutect2, varscan2
- ETDB | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1406880101; called by mutect2, varscan2
- EXOSC6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 153/329 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs934330699; called by muse, mutect2, varscan2
- FCN3 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 130/252 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs202230664; called by muse, mutect2, varscan2
- GAGE2A | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 50/1505 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1557130262; called by muse, mutect2
- GUCY1A2 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 36/593 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs996048439, COSV56477093; called by muse, mutect2
- HGF | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 75/411 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55948411; called by muse, mutect2, varscan2
- HIP1 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 157/637 reads (25%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.97); catalogued as rs368324123, COSV61183642; called by muse, mutect2, varscan2
- HSPBAP1 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 183/303 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs184993518, COSV60244036; called by muse, mutect2, varscan2
- IFI44 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as rs769558871; called by muse, mutect2, varscan2
- IRX2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 32/768 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1415346915; called by muse, mutect2
- KCNC2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 75/514 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs755326940, COSV100129140; called by muse, mutect2, varscan2
- KIF1B | c.4904G>A p.C1635Y (on ENST00000377086 / NM_001365952.1; = p.C1589Y on NM_015074.3) | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs142714491; called by muse, mutect2, varscan2
- LRRC71 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 339/496 reads (68%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs369241615; called by muse, mutect2, varscan2
- MARCHF4 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 264/265 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs910030817, COSV56104657, COSV56104825; called by muse, mutect2, varscan2
- MINDY1 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 149/490 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs1040245529, COSV56498117; called by muse, mutect2, varscan2
- MUC16 | c.7823C>A p.T2608N | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs1185799584; called by muse, mutect2
- MUC17 | c.11810C>G p.T3937R | Missense Mutation (SNP) | VAF 199/893 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); catalogued as rs144836867; called by muse, mutect2, varscan2
- MUC5B | c.15365C>T p.T5122M | Missense Mutation (SNP) | VAF 289/867 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs774969000, COSV71594408; called by muse, mutect2, varscan2
- MYH2 | c.4516C>T p.R1506* | Nonsense Mutation (SNP) | VAF 17/196 reads (9%) | catalogued as COSV55430702; called by muse, mutect2
- MYO6 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV64118458; called by muse, mutect2, varscan2
- NAGA | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 278/598 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs202010344, COSV67170074; called by muse, mutect2, varscan2
- NDUFS5 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs375631916; called by muse, mutect2, varscan2
- NEUROD1 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54550045; called by muse, mutect2
- OR10AG1 | c.38A>T p.N13I | Missense Mutation (SNP) | VAF 120/373 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV56633640; called by muse, mutect2, varscan2
- OR2AJ1 | c.940dup p.M314Nfs*3 | Frame Shift Ins (INS) | VAF 96/262 reads (37%) | catalogued as rs772358764; called by mutect2, varscan2
- OR2J2 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs537704908, COSV65848207; called by muse, mutect2
- OR4C6 | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 135/447 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as rs771673014; called by muse, mutect2, varscan2
- PAPPA2 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 158/534 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV62773268; called by muse, mutect2, varscan2
- PCDHB15 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 221/475 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV51092718; called by muse, mutect2, varscan2
- PCK2 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 142/307 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs750889427; called by muse, mutect2, varscan2
- PSG5 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 134/222 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV100743067; called by muse, mutect2, varscan2
- PXDNL | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 46/332 reads (14%) | catalogued as rs1432085650, COSV62478278, COSV62500583; called by muse, mutect2, varscan2
- RGPD4 | c.4172A>C p.K1391T | Missense Mutation (SNP) | VAF 114/477 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61745230; called by muse, mutect2, varscan2
- RNF17 | c.2939G>A p.R980Q | Missense Mutation (SNP) | VAF 108/305 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0.029); catalogued as rs768777758, COSV99693307; called by muse, mutect2, varscan2
- RORC | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222050210, COSV59093924, COSV59094041; called by muse, mutect2, varscan2
- RP1 | c.5339G>A p.S1780N | Missense Mutation (SNP) | VAF 122/235 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV55125199; called by muse, mutect2, varscan2
- SCAMP5 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 74/687 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62643261; called by muse, mutect2, varscan2
- SCN4A | c.3622G>C p.E1208Q | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.505); catalogued as rs754401226, COSV71125927, COSV71129787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TASOR | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396800311, COSV62930099; called by muse, mutect2, varscan2
- TMEM94 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 211/448 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs1379619282; called by muse, mutect2, varscan2
- TRIM51 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 119/371 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs1249359165, COSV55266215; called by muse, mutect2, varscan2
- UBP1 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 288/448 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52144730; called by muse, mutect2, varscan2
- UBR1 | c.3838G>A p.V1280I | Missense Mutation (SNP) | VAF 83/154 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs774045909; called by muse, mutect2, varscan2
- UGT3A1 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 110/367 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs554821154, COSV57095384; called by muse, mutect2, varscan2
- UNC5D | c.2056T>C p.C686R | Missense Mutation (SNP) | VAF 176/410 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV54829147; called by muse, mutect2, varscan2
- UNC80 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.59); catalogued as rs752072537, COSV55912649; called by muse, mutect2, varscan2
- ZC3H11B | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 295/472 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1009943141, COSV65845046; called by muse, mutect2, varscan2
- ZNF333 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 190/350 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as rs746332613, COSV52884664; called by muse, mutect2, varscan2
- ZNF579 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 429/788 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.14); catalogued as rs1274385611; called by muse, mutect2, varscan2
- ZPBP2 | c.464G>A p.C155Y (on ENST00000348931 / NM_199321.3; = p.C133Y on NM_198844.3) | Missense Mutation (SNP) | VAF 179/406 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766363930; called by muse, mutect2, varscan2
- AC138207.8 | n.308G>A | Splice Region (SNP) | VAF 67/118 reads (57%) | called by muse, mutect2, varscan2
- ACOX1 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 163/333 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTN2 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 151/439 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFM | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 50/512 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.844); called by muse, mutect2
- ANAPC1 | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ANGPTL5 | c.505A>T p.I169L | Missense Mutation (SNP) | VAF 168/335 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by mutect2, varscan2
- ARID3B | c.398G>C p.R133T | Missense Mutation (SNP) | VAF 75/514 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BTG4 | c.72A>C p.K24N | Missense Mutation (SNP) | VAF 104/529 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- C7orf25 | c.1172G>C p.S391T | Missense Mutation (SNP) | VAF 129/551 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CHD6 | c.1976_1977dup p.G660Lfs*4 | Frame Shift Ins (INS) | VAF 86/586 reads (15%) | called by mutect2, pindel, varscan2
- CHRDL1 | c.594T>G p.H198Q (on ENST00000372045; = p.H204Q on NM_145234.4) | Missense Mutation (SNP) | VAF 114/229 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CNTN5 | c.3056G>T p.S1019I | Missense Mutation (SNP) | VAF 20/419 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- CRYBG3 | c.4252A>C p.N1418H | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.229); called by muse, mutect2
- DOCK4 | c.5893C>T p.Q1965* | Nonsense Mutation (SNP) | VAF 131/544 reads (24%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.3598G>A p.A1200T | Missense Mutation (SNP) | VAF 289/953 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EHHADH | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ELAVL4 | c.563A>G p.E188G | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- F13B | c.1674C>A p.F558L | Missense Mutation (SNP) | VAF 13/411 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- FAM180B | c.503_508del p.R168_P169del | In Frame Del (DEL) | VAF 130/565 reads (23%) | called by mutect2, pindel, varscan2
- FAM205C | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 135/457 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FAM47A | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 119/449 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLG | c.10445C>A p.S3482Y | Missense Mutation (SNP) | VAF 67/543 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GTPBP1 | c.605A>T p.E202V | Missense Mutation (SNP) | VAF 183/369 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HEATR9 | c.443A>C p.Q148P | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KIF7 | c.3340C>G p.Q1114E | Missense Mutation (SNP) | VAF 199/592 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMA4 | c.2329G>T p.A777S (on ENST00000230538 / NM_001105206.3; = p.A770S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- MACROD2 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 11/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MAP1S | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 114/279 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- MAPRE2 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MAST2 | c.226C>G p.P76A | Missense Mutation (SNP) | VAF 118/224 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MDGA2 | c.967G>A p.V323I (on ENST00000399232 / NM_001113498.2; = p.V25I on NM_182830.4) | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MEGF6 | c.4258+1G>A p.X1420_splice | Splice Site (SNP) | VAF 176/327 reads (54%) | called by muse, mutect2, varscan2
- MTA1 | c.1319G>A p.R440K | Missense Mutation (SNP) | VAF 135/448 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NPY | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 64/495 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTN1 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 109/301 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR6K3 | c.317A>G p.K106R (on ENST00000368146; = p.K90R on NM_001005327.2) | Missense Mutation (SNP) | VAF 266/430 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OTOG | c.3364dup p.T1122Nfs*4 | Frame Shift Ins (INS) | VAF 54/387 reads (14%) | called by mutect2, pindel, varscan2
- PCOLCE2 | c.57G>C p.Q19H | Missense Mutation (SNP) | VAF 68/522 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEG3 | c.1304G>T p.S435I | Missense Mutation (SNP) | VAF 124/226 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PTPN22 | c.2168C>G p.T723S (on ENST00000359785 / NM_001193431.2; = p.T668S on NM_012411.5) | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- RASL11B | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 205/445 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SERPINA12 | c.408C>A p.N136K | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SNRK | c.1289C>A p.A430E | Missense Mutation (SNP) | VAF 73/464 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TRIM65 | c.760C>A p.Q254K | Missense Mutation (SNP) | VAF 179/367 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UNC80 | c.1328T>A p.F443Y | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- WDR81 | c.5605T>C p.S1869P (on ENST00000409644 / NM_001163809.2; = p.S818P on NM_152348.4) | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF148 | c.715A>T p.K239* | Nonsense Mutation (SNP) | VAF 72/242 reads (30%) | called by muse, mutect2, varscan2
- ZNF814 | c.624G>T p.Q208H | Missense Mutation (SNP) | VAF 138/342 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF831 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 98/1168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCA13 | c.8940G>A p.A2980= | Silent (SNP) | VAF 168/345 reads (49%) | catalogued as rs750609118, COSV71287131; called by muse, mutect2, varscan2
- ADGRL3 | c.309C>T p.S103= (on ENST00000506720 / NM_001322402.2; = p.S35= on NM_015236.6) | Silent (SNP) | VAF 106/258 reads (41%) | called by muse, mutect2, varscan2
- ASB18 | c.1017C>T p.C339= | Silent (SNP) | VAF 338/650 reads (52%) | catalogued as rs764175796; called by muse, mutect2
- AURKA | c.348A>C p.S116= | Silent (SNP) | VAF 87/389 reads (22%) | called by muse, mutect2, varscan2
- AUTS2 | c.111C>T p.G37= | Silent (SNP) | VAF 299/1055 reads (28%) | called by muse, mutect2, varscan2
- C2orf16 | c.5637T>C p.S1879= | Silent (SNP) | VAF 75/388 reads (19%) | called by muse, mutect2, varscan2
- CD33 | c.213T>C p.S71= | Silent (SNP) | VAF 222/401 reads (55%) | called by muse, mutect2, varscan2
- CHRM2 | c.1320T>C p.Y440= | Silent (SNP) | VAF 60/443 reads (14%) | called by muse, mutect2, varscan2
- CIART | c.873C>T p.G291= | Silent (SNP) | VAF 482/738 reads (65%) | catalogued as rs782717183, COSV99289993; called by muse, mutect2, varscan2
- CLTCL1 | c.2328C>T p.I776= | Silent (SNP) | VAF 128/265 reads (48%) | catalogued as rs782066280, COSV54225221; called by muse, mutect2, varscan2
- CNTRL | c.5025G>A p.Q1675= | Silent (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2, varscan2
- CSMD2 | c.1602C>T p.G534= | Silent (SNP) | VAF 16/422 reads (4%) | called by muse, mutect2
- CTPS1 | c.987C>T p.N329= | Silent (SNP) | VAF 45/232 reads (19%) | called by muse, mutect2, varscan2
- FBXO15 | c.204C>T p.S68= | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- GRIN2D | c.3732C>T p.A1244= | Silent (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- H4C2 | c.12C>T p.R4= | Silent (SNP) | VAF 17/228 reads (7%) | catalogued as rs569686893; called by muse, mutect2
- IQGAP1 | c.729G>A p.P243= | Silent (SNP) | VAF 153/478 reads (32%) | catalogued as rs766453620, COSV51586745; called by muse, mutect2, varscan2
- IQGAP2 | c.1188C>T p.S396= | Silent (SNP) | VAF 24/378 reads (6%) | called by muse, mutect2
- KCNB1 | c.1962C>T p.I654= | Silent (SNP) | VAF 77/766 reads (10%) | catalogued as rs1226209770; called by muse, mutect2, varscan2
- MDN1 | c.8685C>A p.A2895= | Silent (SNP) | VAF 18/378 reads (5%) | called by muse, mutect2
- MRGPRE | c.666C>T p.T222= | Silent (SNP) | VAF 285/888 reads (32%) | catalogued as rs762643196; called by muse, mutect2, varscan2
- MS4A7 | c.21C>T p.T7= | Silent (SNP) | VAF 47/249 reads (19%) | called by muse, mutect2, varscan2
- MTUS2 | c.1749G>A p.T583= | Silent (SNP) | VAF 247/606 reads (41%) | catalogued as rs757126872, COSV70917100; called by muse, mutect2, varscan2
- NDST1 | c.1800G>A p.T600= | Silent (SNP) | VAF 203/407 reads (50%) | catalogued as rs778115933; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFATC1 | c.2616G>A p.T872= (on ENST00000427363 / NM_001278669.2; = p.T859= on NM_172387.3) | Silent (SNP) | VAF 310/310 reads (100%) | catalogued as rs372417669; called by muse, varscan2
- OBSCN | c.8517G>A p.A2839= | Silent (SNP) | VAF 382/382 reads (100%) | catalogued as rs374034858; called by muse, mutect2, varscan2
- PCDHGB1 | c.753C>T p.N251= | Silent (SNP) | VAF 150/306 reads (49%) | catalogued as rs767340665, COSV53929025; called by muse, mutect2, varscan2
- PCLO | c.1890G>A p.T630= | Silent (SNP) | VAF 66/301 reads (22%) | catalogued as rs766820629, COSV61637666; called by muse, mutect2, varscan2
- RASIP1 | c.1203G>A p.T401= | Silent (SNP) | VAF 151/364 reads (41%) | catalogued as rs147351682; called by muse, mutect2, varscan2
- RP1 | c.2352C>T p.N784= | Silent (SNP) | VAF 18/279 reads (6%) | catalogued as rs1316922954; called by muse, mutect2
- SALL2 | c.2094G>A p.K698= | Silent (SNP) | VAF 203/406 reads (50%) | called by muse, mutect2, varscan2
- SLC7A3 | c.1521G>C p.L507= | Silent (SNP) | VAF 170/388 reads (44%) | called by muse, mutect2, varscan2
- SLITRK6 | c.84A>G p.R28= | Silent (SNP) | VAF 24/453 reads (5%) | catalogued as rs748461212; called by muse, mutect2
- TDRKH | c.1371C>T p.S457= | Silent (SNP) | VAF 46/411 reads (11%) | called by muse, mutect2, varscan2
- TOX3 | c.1608C>T p.V536= | Silent (SNP) | VAF 318/319 reads (100%) | catalogued as rs779161107, COSV54865731; called by muse, mutect2, varscan2
- ZMAT1 | c.777C>T p.V259= | Silent (SNP) | VAF 333/333 reads (100%) | catalogued as rs372023196, COSV65658425; called by muse, mutect2, varscan2
- ZNF443 | c.1225C>A p.R409= | Silent (SNP) | VAF 79/272 reads (29%) | catalogued as COSV56893439; called by muse, mutect2, varscan2
- ZRANB3 | c.2790T>C p.S930= | Silent (SNP) | VAF 156/478 reads (33%) | called by muse, mutect2, varscan2
- MFSD5 | chr12:53251971 C>T | 5'Flank (SNP) | VAF 207/611 reads (34%) | called by muse, mutect2, varscan2
- SMIM23 | c.434+41G>A | Intron (SNP) | VAF 13/272 reads (5%) | catalogued as rs1275524218; called by muse, mutect2
